Somatic mutation profile of cancer-model specimen HCM-CSHL-0080-C25-85A (3D Organoid; aliquot HCM-CSHL-0080-C25-85A-01D-A77E-36), derived from the primary tumor of HCMI case HCM-CSHL-0080-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 60.9 years (22,238 days).
Specimen HCM-CSHL-0080-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6209b5f4-30b5-4add-891b-b56e9c0272f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0080-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0080-C25-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35286188-bd30-4f82-a5fb-cbb1020bdf24

The open-access MAF lists 107 somatic variants for this specimen: 68 protein-altering or splice-affecting, 24 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 24, 3'UTR 5, Nonsense Mutation 5, Intron 4, Frame Shift Ins 3, 5'Flank 2, In Frame Ins 2, 5'UTR 2, Splice Region 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 336/336 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM071585, CM973278, COSV58682998, COSV58690035, COSV58690777, COSV58726216; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 139/305 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SRP72 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs387907189, CM123465; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM29 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs537404539, COSV63660881; called by muse, mutect2, varscan2
- ADCK1 | c.1483C>T p.L495F | Missense Mutation (SNP) | VAF 72/166 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as rs766207920; called by muse, mutect2, varscan2
- BZW1 | c.854dup p.N285Kfs*54 | Frame Shift Ins (INS) | VAF 38/66 reads (58%) | catalogued as rs774640795; called by mutect2, varscan2
- C16orf78 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 54/289 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs747758290, COSV100147604; called by muse, mutect2, varscan2
- CADM1 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 115/486 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.166); catalogued as rs1216125604, COSV59010956; called by muse, mutect2, varscan2
- CALN1 | c.446C>T p.T149M (on ENST00000329008 / NM_001017440.3; = p.T191M on NM_031468.4) | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1221196771, COSV100204838; called by muse, mutect2, varscan2
- CARMIL3 | c.4075C>T p.R1359W | Missense Mutation (SNP) | VAF 108/265 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.062); catalogued as rs139310553; called by muse, mutect2, varscan2
- CEP152 | c.3922G>A p.A1308T (on ENST00000380950 / NM_001194998.2; = p.A1252T on NM_014985.4) | Missense Mutation (SNP) | VAF 68/466 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as rs556909247, COSV57858219; called by muse, mutect2, varscan2
- CES4A | c.1240C>T p.R414* | Nonsense Mutation (SNP) | VAF 136/306 reads (44%) | catalogued as rs755629060; called by muse, mutect2, varscan2
- CHRNA7 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 134/2340 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs759662036; called by muse, mutect2
- CHST3 | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); catalogued as rs868684674; called by muse, mutect2, varscan2
- CLDN16 | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374751726; called by muse, mutect2, varscan2
- CLEC4F | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1408823470, COSV55480202; called by muse, mutect2, varscan2
- COL11A2 | c.1489C>T p.R497C (on ENST00000341947 / NM_080680.3; = p.R390C on NM_080679.2) | Missense Mutation (SNP) | VAF 145/505 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752552097; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL14A1 | c.5116G>A p.V1706I | Missense Mutation (SNP) | VAF 121/122 reads (99%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs773249922, COSV52848739, COSV52851506; called by muse, mutect2, varscan2
- CPSF7 | c.535C>T p.R179* (on ENST00000394888 / NM_001136040.4; = p.R222* on NM_024811.4) | Nonsense Mutation (SNP) | VAF 37/166 reads (22%) | catalogued as rs768549870; called by muse, mutect2, varscan2
- CRYGD | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 153/460 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as COSV52205407; called by muse, mutect2, varscan2
- DDX11 | c.2638T>A p.C880S (on ENST00000545668 / NM_152438.2; = p.R831= on NM_004399.3) | Missense Mutation (SNP) | VAF 303/594 reads (51%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV52504146; called by muse, mutect2, varscan2
- DDX58 | c.611T>A p.M204K | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0.035); catalogued as COSV65884447; called by muse, mutect2
- DPYSL5 | c.1105G>T p.D369Y | Missense Mutation (SNP) | VAF 151/233 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56516776; called by muse, mutect2, varscan2
- FGD5 | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.273); catalogued as rs560710091, COSV53250204; called by muse, mutect2, varscan2
- FURIN | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 75/752 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs772432840; called by muse, mutect2, varscan2
- GMPPA | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 85/143 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs752643023, COSV58007111; called by muse, mutect2, varscan2
- HS6ST1 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs766927296; called by muse, mutect2, varscan2
- INPP4A | c.2549G>A p.R850H (on ENST00000074304 / NM_001134224.1; = p.R811H on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.07); catalogued as rs766300586, COSV50791785; called by muse, mutect2, varscan2
- KSR2 | c.1660C>T p.R554W | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.919); catalogued as rs778353655; called by muse, mutect2, varscan2
- MAP3K3 | c.1805G>A p.R602H | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.553); catalogued as rs770706062; called by muse, mutect2, varscan2
- MAST1 | c.2105G>A p.R702H | Missense Mutation (SNP) | VAF 87/235 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as rs759443859, COSV52242416; called by muse, mutect2, varscan2
- OR5H14 | c.97G>T p.V33L | Missense Mutation (SNP) | VAF 81/193 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs774245498, COSV71193694; called by muse, mutect2, varscan2
- P3H3 | c.540_542del p.F181del | In Frame Del (DEL) | VAF 160/854 reads (19%) | catalogued as rs781882653; called by pindel, varscan2
- PLEKHG3 | c.1538C>T p.T513I (on ENST00000394691; = p.T569I on NM_001308147.2) | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV55983948; called by muse, mutect2, varscan2
- SDK1 | c.5180C>T p.P1727L | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs548946940, COSV67358000; called by muse, mutect2, varscan2
- SLC2A5 | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 54/446 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV66235744; called by muse, mutect2, varscan2
- TOE1 | c.1421A>G p.N474S | Missense Mutation (SNP) | VAF 218/352 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1419413327; called by muse, mutect2, varscan2
- TSHZ3 | c.107C>T p.T36M | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs201181883; called by muse, mutect2, varscan2
- VSTM4 | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 79/166 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.271); catalogued as rs769295438, COSV100251938, COSV60525001; called by muse, mutect2, varscan2
- YBX1 | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 129/457 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as rs1462110527, COSV100172212; called by muse, mutect2, varscan2
- ZNF560 | c.1577C>T p.T526I | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs780300268; called by muse, mutect2, varscan2
- ADCY10 | c.3250G>A p.A1084T | Missense Mutation (SNP) | VAF 162/267 reads (61%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- APOB | c.1125C>T p.S375= | Splice Region (SNP) | VAF 124/498 reads (25%) | called by muse, mutect2, varscan2
- ARMCX2 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 100/211 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- CDC42EP1 | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 105/169 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- EXTL3 | c.2123G>A p.W708* | Nonsense Mutation (SNP) | VAF 124/306 reads (41%) | called by muse, mutect2, varscan2
- H1-7 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 322/652 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- HTR1E | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0); called by mutect2, varscan2
- LATS1 | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- MCM7 | c.1882G>T p.E628* | Nonsense Mutation (SNP) | VAF 74/284 reads (26%) | called by muse, varscan2
- MED26 | c.1019G>A p.C340Y | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- MRO | c.507dup p.F170Ifs*7 | Frame Shift Ins (INS) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- MTUS1 | c.708_712dup p.A238Efs*6 | Frame Shift Ins (INS) | VAF 46/52 reads (88%) | called by mutect2, pindel, varscan2
- MUC6 | c.5126C>T p.T1709I | Missense Mutation (SNP) | VAF 28/822 reads (3%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2
- NCOA6 | c.907C>T p.R303* | Nonsense Mutation (SNP) | VAF 100/413 reads (24%) | called by muse, mutect2, varscan2
- NIPBL | c.7406A>G p.K2469R | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- OR10J1 | c.250A>G p.S84G | Missense Mutation (SNP) | VAF 83/253 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OR2J3 | c.611T>C p.I204T | Missense Mutation (SNP) | VAF 83/282 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- OR5A2 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PRAMEF14 | c.953G>T p.S318I | Missense Mutation (SNP) | VAF 93/398 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SRRM2 | c.4796_4801dup p.S1600_S1601insCS | In Frame Ins (INS) | VAF 134/215 reads (62%) | called by mutect2, pindel, varscan2
- SYNE2 | c.14710C>A p.Q4904K | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TBCE | c.1319T>C p.I440T (on ENST00000366601; = p.I503T on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 263/424 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- TMEM121 | c.575_576insACT p.L192dup | In Frame Ins (INS) | VAF 167/379 reads (44%) | called by mutect2, pindel, varscan2
- TP53 | c.856_869del p.E286Qfs*15 | Frame Shift Del (DEL) | VAF 350/395 reads (89%) | called by mutect2, pindel, varscan2
- ULBP2 | c.594G>C p.L198F | Missense Mutation (SNP) | VAF 87/235 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- USP17L10 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 219/518 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); called by mutect2, varscan2
- ZNF763 | c.392A>C p.H131P (on ENST00000358987 / NM_001367172.2; = p.H134P on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- ANTXR1 | c.1137C>T p.D379= | Silent (SNP) | VAF 116/414 reads (28%) | catalogued as rs775392233, COSV58011787; called by muse, mutect2, varscan2
- ARHGEF33 | c.1761G>A p.P587= | Silent (SNP) | VAF 94/252 reads (37%) | catalogued as rs1399287312; called by muse, mutect2, varscan2
- BRINP2 | c.201C>T p.R67= | Silent (SNP) | VAF 168/254 reads (66%) | catalogued as rs138435872; called by muse, mutect2, varscan2
- DCDC1 | c.4554C>T p.S1518= (on ENST00000597505 / NM_001367979.1; = p.S625= on NM_020869.3) | Silent (SNP) | VAF 26/120 reads (22%) | catalogued as rs1237416222, COSV58002645; called by muse, mutect2, varscan2
- DCHS1 | c.4314C>T p.R1438= | Silent (SNP) | VAF 183/814 reads (22%) | catalogued as rs754583495, COSV55030352; called by muse, mutect2, varscan2
- DES | c.312G>A p.T104= | Silent (SNP) | VAF 165/540 reads (31%) | catalogued as COSV64660606; called by muse, mutect2, varscan2
- ECT2L | c.1533G>A p.A511= | Silent (SNP) | VAF 29/112 reads (26%) | catalogued as rs763552266, COSV62885871; called by muse, mutect2, varscan2
- FASN | c.132C>T p.L44= | Silent (SNP) | VAF 195/837 reads (23%) | called by muse, mutect2, varscan2
- KRT37 | c.285C>T p.Y95= | Silent (SNP) | VAF 185/572 reads (32%) | catalogued as rs146872723; called by muse, mutect2, varscan2
- LCOR | c.3120C>T p.T1040= | Silent (SNP) | VAF 50/146 reads (34%) | called by muse, mutect2, varscan2
- NBEA | c.249C>T p.V83= | Silent (SNP) | VAF 51/160 reads (32%) | called by muse, mutect2, varscan2
- OR5K1 | c.45A>G p.T15= | Silent (SNP) | VAF 34/70 reads (49%) | called by muse, varscan2
- PCDHGB2 | c.2118G>A p.A706= | Silent (SNP) | VAF 172/375 reads (46%) | catalogued as COSV53951362, COSV54061452; called by muse, mutect2, varscan2
- POM121L12 | c.480C>T p.P160= | Silent (SNP) | VAF 82/227 reads (36%) | catalogued as rs769352697; called by muse, mutect2, varscan2
- PROB1 | c.990C>T p.P330= | Silent (SNP) | VAF 100/186 reads (54%) | called by muse, mutect2, varscan2
- PTPRM | c.4326C>T p.Y1442= | Silent (SNP) | VAF 45/133 reads (34%) | catalogued as rs777980694; called by muse, mutect2, varscan2
- SOS1 | c.483T>C p.D161= | Silent (SNP) | VAF 43/138 reads (31%) | catalogued as rs1553362598; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPATS2L | c.1128G>A p.A376= | Silent (SNP) | VAF 102/376 reads (27%) | catalogued as rs752637429; called by muse, mutect2, varscan2
- SPEG | c.669G>A p.R223= | Silent (SNP) | VAF 80/261 reads (31%) | catalogued as rs1266504480, COSV56665871; called by muse, mutect2, varscan2
- TDP2 | c.192T>G p.P64= | Silent (SNP) | VAF 115/290 reads (40%) | called by muse, mutect2, varscan2
- TMEM40 | c.585C>T p.A195= | Silent (SNP) | VAF 100/196 reads (51%) | called by muse, mutect2, varscan2
- TSR1 | c.531C>T p.L177= | Silent (SNP) | VAF 6/126 reads (5%) | called by muse, mutect2
- XPR1 | c.1470G>A p.V490= | Silent (SNP) | VAF 196/317 reads (62%) | called by muse, mutect2, varscan2
- ZNF610 | c.657T>C p.L219= | Silent (SNP) | VAF 43/177 reads (24%) | catalogued as rs559281988, COSV58345002; called by muse, mutect2, varscan2
- AFG3L2 | c.-95C>T | 5'UTR (SNP) | VAF 161/444 reads (36%) | called by muse, mutect2, varscan2
- ARFGAP3 | chr22:42858461 G>A | 5'Flank (SNP) | VAF 119/185 reads (64%) | catalogued as rs1255282637; called by muse, mutect2, varscan2
- CEACAM19 | c.-9G>T | 5'UTR (SNP) | VAF 44/314 reads (14%) | catalogued as rs958116144; called by muse, mutect2, varscan2
- CPLANE1 | c.*5482G>A | 3'UTR (SNP) | VAF 50/159 reads (31%) | catalogued as rs772723784; called by muse, mutect2, varscan2
- DLC1 | c.1349-17287C>T | Intron (SNP) | VAF 122/275 reads (44%) | catalogued as rs1400383849; called by muse, mutect2, varscan2
- FADS2 | chr11:61826125 A>G | 5'Flank (SNP) | VAF 17/190 reads (9%) | catalogued as rs1034495108; called by muse, mutect2
- FAM157B | n.8C>T | RNA (SNP) | VAF 161/930 reads (17%) | catalogued as rs772980111; called by muse, mutect2, varscan2
- HLA-DQA1 | c.82+1402_82+1413delinsTGGACAGTG | Intron (DEL) | VAF 6/39 reads (15%) | called by pindel, varscan2*
- KRT74 | c.1135-46A>G | Intron (SNP) | VAF 44/155 reads (28%) | called by muse, mutect2, varscan2
- KRTAP5-2 | c.*26del | 3'UTR (DEL) | VAF 31/207 reads (15%) | called by mutect2, pindel
- LDHA | chr11:18408066 A>G | 3'Flank (SNP) | VAF 41/156 reads (26%) | called by muse, mutect2, varscan2
- TMC8 | c.1252-10T>G | Intron (SNP) | VAF 205/332 reads (62%) | catalogued as rs1414247439; called by muse, mutect2, varscan2
- UMPS | c.*5131_*5132insT | 3'UTR (INS) | VAF 21/57 reads (37%) | catalogued as rs769492763; called by mutect2, pindel, varscan2
- ZNF223 | c.*8A>G | 3'UTR (SNP) | VAF 38/82 reads (46%) | called by muse, mutect2, varscan2
- ZNF714 | c.*833T>C | 3'UTR (SNP) | VAF 33/66 reads (50%) | catalogued as rs1311350639; called by muse, mutect2, varscan2
